Somatic mutation profile of tumor specimen C3N-02727-02 (aliquot CPT0177710006) from CPTAC case C3N-02727, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.9 years (18,210 days).
Specimen C3N-02727-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bfb1a14-cdf1-47e7-a55e-05a6008e7ae0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02727-71 (Blood Derived Normal), aliquot CPT0177820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35a5425f-b119-490d-8e47-caa65c54cf0c

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Intron 9, Nonsense Mutation 6, 3'UTR 2, RNA 2, Frame Shift Del 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 50/273 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3526G>A p.G1176S | Missense Mutation (SNP) | VAF 77/730 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs780183402; called by muse, mutect2, varscan2
- ADGRA3 | c.3725C>G p.A1242G | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51566354; called by muse, mutect2, varscan2
- AGBL3 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99311389; called by muse, mutect2
- APOBR | c.1601G>T p.S534I (on ENST00000431282; = p.S543I on NM_018690.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV100112471; called by muse, mutect2
- ARHGAP35 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68333703; called by muse, mutect2, varscan2
- CFAP61 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs759937819, COSV55626654; called by muse, mutect2
- CPNE6 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.234); catalogued as rs200912343; called by muse, mutect2, varscan2
- CSMD1 | c.4324C>A p.Q1442K (on ENST00000520002; = p.Q1441K on NM_033225.6) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1298544802; called by muse, mutect2, varscan2
- DDX54 | c.2263_2264del p.S755Rfs*23 | Frame Shift Del (DEL) | VAF 26/249 reads (10%) | catalogued as rs751518629; called by pindel, varscan2
- DENND3 | c.1817C>G p.P606R | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV52805564; called by muse, mutect2, varscan2
- DIP2A | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1385997588; called by muse, mutect2
- DNAJC6 | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373326537; called by muse, mutect2
- DOCK3 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56517905; called by muse, mutect2
- FBN1 | c.6448C>T p.R2150C | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs76702162, CM090450, COSV57312375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR179 | c.1547G>A p.R516Q (on ENST00000621958; = p.R515Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/527 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs369293710; called by muse, mutect2
- GPSM1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV52517618; called by muse, mutect2, varscan2
- GTPBP6 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 97/875 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755353457, COSV58205261; called by muse, mutect2, varscan2
- KMT2B | c.7258A>G p.S2420G | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV55821336; called by muse, mutect2, varscan2
- MAML1 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 25/331 reads (8%) | catalogued as COSV99483158; called by muse, mutect2
- MC4R | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs756424832; called by muse, mutect2
- NEK1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as rs780469027; called by muse, mutect2, varscan2
- NUP155 | c.3359G>A p.R1120Q (on ENST00000231498 / NM_153485.3; = p.R1061Q on NM_004298.4) | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373119361; called by muse, mutect2, varscan2
- OR4P4 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV58920611; called by muse, mutect2, varscan2
- PLCB4 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV53793141; called by muse, mutect2
- QSER1 | c.59C>G p.T20S (on ENST00000399302; = p.T149S on NM_001076786.3) | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV67901612; called by muse, mutect2
- RELN | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as COSV59023800, COSV59036404; called by muse, mutect2
- SCNM1 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54859987, COSV54861191; called by muse, mutect2
- SLAMF6 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs758426351, COSV100924891, COSV100924923; called by muse, mutect2
- TCHH | c.3646G>C p.D1216H | Missense Mutation (SNP) | VAF 35/479 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs746634817, COSV64275839; called by muse, mutect2
- USH2A | c.13023C>A p.C4341* | Nonsense Mutation (SNP) | VAF 26/269 reads (10%) | catalogued as COSV100243164; called by muse, mutect2
- ABCA8 | c.3058C>A p.L1020I | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ADAMTS1 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APBA2 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG16L1 | c.341A>T p.N114I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- BUD13 | c.1853A>G p.D618G | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARM1 | c.190_200del p.P64Gfs*8 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- CCDC57 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- DDB1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- DENND3 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FAM47C | c.2927T>A p.L976H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.2018G>A p.R673K | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- HACD3 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRS2 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ITPR2 | c.4265C>T p.A1422V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); called by muse, mutect2
- MYO1B | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2
- MYO6 | c.1818A>C p.E606D | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NAV2 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2
- NFAT5 | c.4448G>A p.G1483D | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR2T29 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 13/480 reads (3%) | called by muse, mutect2
- OR5B21 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
- PAPPA | c.3566T>C p.L1189P | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.664); called by muse, mutect2
- PLPPR5 | c.307A>C p.T103P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- PPP6R2 | c.1751A>C p.E584A (on ENST00000216061 / NM_001365836.1; = p.E557A on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRUNE2 | c.8605G>A p.E2869K | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- SH3BP2 | c.834C>A p.S278R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- SHMT2 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); called by muse, mutect2
- SLC22A12 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- SYT8 | c.1100_1126del p.R367_P375del | In Frame Del (DEL) | VAF 24/280 reads (9%) | called by mutect2, pindel
- TEX13C | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.708); called by muse, mutect2
- TRIP12 | c.5178G>A p.M1726I | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2
- USP14 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- USP17L2 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 84/2344 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- YPEL1 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- ZNF492 | c.1514A>T p.Y505F | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2
- ZNF524 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAM2 | c.1914A>C p.S638= | Silent (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2
- BPI | c.1380G>A p.T460= (on ENST00000262865; = p.T456= on NM_001725.3) | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as rs748457241; called by muse, mutect2
- CCDC88A | c.3828T>C p.N1276= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- CLEC14A | c.543G>C p.A181= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as COSV60563425; called by muse, mutect2
- DGKZ | c.2436G>A p.Q812= (on ENST00000454345 / NM_001105540.2; = p.Q624= on NM_003646.4) | Silent (SNP) | VAF 27/526 reads (5%) | catalogued as COSV58989705; called by muse, mutect2
- ICA1 | c.723T>C p.F241= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs1267887767; called by muse, mutect2, varscan2
- KMT2A | c.1428C>T p.S476= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- LTN1 | c.3411A>G p.E1137= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- MAK | c.1182G>A p.R394= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- OR56A4 | c.393C>T p.T131= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs569446273, COSV100417470, COSV58109197; called by muse, mutect2
- PCSK2 | c.1731C>T p.S577= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs145152141; called by muse, mutect2, varscan2
- RIMBP3 | c.3114G>A p.V1038= | Silent (SNP) | VAF 74/1402 reads (5%) | called by muse, mutect2
- SFRP4 | c.549G>A p.V183= | Silent (SNP) | VAF 37/261 reads (14%) | catalogued as COSV101460869; called by muse, mutect2, varscan2
- SGCZ | c.306A>T p.P102= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- STAM | c.1485C>T p.V495= | Silent (SNP) | VAF 58/622 reads (9%) | catalogued as rs1554830564; called by muse, mutect2
- TBR1 | c.1830C>G p.S610= | Silent (SNP) | VAF 26/376 reads (7%) | catalogued as rs908576997; called by muse, mutect2
- TRIM55 | c.111G>A p.V37= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as rs748053046; called by muse, mutect2, varscan2
- UBAC2 | c.747G>A p.L249= (on ENST00000403766 / NM_001144072.2; = p.L214= on NM_177967.4) | Silent (SNP) | VAF 28/285 reads (10%) | called by muse, mutect2
- USH2A | c.14289G>A p.G4763= | Silent (SNP) | VAF 49/506 reads (10%) | catalogued as CD166027; called by muse, mutect2
- ZNF213 | c.858G>A p.P286= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs764726274; called by muse, mutect2, varscan2
- BEND6 | c.299-618A>C | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as COSV66067916; called by muse, mutect2, varscan2
- CPNE2 | c.927+893G>C | Intron (SNP) | VAF 12/154 reads (8%) | catalogued as rs1234986922; called by muse, mutect2
- CPSF7 | c.273+104G>T | Intron (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- FAM20A | c.*1944T>A | 3'UTR (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- KRT18P55 | n.1133G>A | RNA (SNP) | VAF 25/224 reads (11%) | called by muse, mutect2, varscan2
- MCF2L | c.169+6894C>G | Intron (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8027-53A>G | Intron (SNP) | VAF 10/62 reads (16%) | catalogued as rs771373945; called by muse, mutect2, varscan2
- NAV3 | c.2024-12815G>T | Intron (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- PADI4 | c.340+379C>T | Intron (SNP) | VAF 13/184 reads (7%) | catalogued as rs1356248989; called by muse, mutect2
- PPP1R8 | c.117+1726T>A | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3702T>C | RNA (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- SEMA6C | c.*72G>A | 3'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- SF3B4 | c.-4C>T | 5'UTR (SNP) | VAF 41/422 reads (10%) | catalogued as rs1553766271; called by muse, mutect2
- TNFAIP8 | c.32-1411C>T | Intron (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
